Somatic mutation profile of tumor specimen b292e992-0611-4254-872f-af8275 (aliquot b292e992-0611-4254-872f-af8275_D6_1) from CPTAC case 18BR004, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct and mucinous carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.7 years (28,013 days).
Specimen b292e992-0611-4254-872f-af8275: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a942e852-8655-4a6e-9c60-5356074518d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f2d0d540-c092-4404-9ce2-bd5e15 (Blood Derived Normal), aliquot f2d0d540-c092-4404-9ce2-bd5e15_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d07fc36e-912f-4fe5-84e7-884ff2434675

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 2, 3'UTR 2, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 114/378 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67139521; called by muse, varscan2
- COL14A1 | c.1580C>G p.T527R | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV52866169; called by muse, mutect2, varscan2
- FABP5 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.309); catalogued as COSV99793153; called by muse, mutect2, varscan2
- FAF1 | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV100875527; called by muse, mutect2, varscan2
- H3-3B | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54665444, COSV54665858, COSV54666236; called by muse, mutect2, varscan2
- KRT14 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1427865521, COSV51423464; called by muse, mutect2, varscan2
- LPP | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 125/294 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs1464159795; called by muse, mutect2, varscan2
- SEMA5A | c.2540G>T p.W847L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750691980; called by muse, mutect2, varscan2
- TNC | c.4027G>A p.V1343I | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs145446426; called by muse, mutect2, varscan2
- WDR91 | c.1591G>C p.G531R | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100615495; called by muse, mutect2, varscan2
- AP3D1 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAT | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 187/485 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IQGAP3 | c.4480C>G p.L1494V | Missense Mutation (SNP) | VAF 119/448 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MN1 | c.3215C>T p.A1072V | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); called by muse, mutect2
- PBX1 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.589); called by muse, mutect2
- TNIP1 | c.458_463dup p.E153_D154dup | In Frame Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- TRBV28 | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- XXYLT1 | c.290T>G p.V97G | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- XYLT2 | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP2B4 | c.2523C>T p.S841= | Silent (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- DIP2C | c.3333C>T p.I1111= | Silent (SNP) | VAF 122/386 reads (32%) | catalogued as rs1384329884; called by muse, mutect2, varscan2
- FAM122A | c.177G>A p.R59= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- PAXIP1 | c.3159G>T p.L1053= | Silent (SNP) | VAF 24/209 reads (11%) | catalogued as rs962856707, COSV66898924; called by muse, mutect2, varscan2
- SP110 | c.1410G>A p.E470= | Silent (SNP) | VAF 30/338 reads (9%) | catalogued as rs1373991241; called by muse, mutect2
- KCNQ2 | c.*30G>A | 3'UTR (SNP) | VAF 65/179 reads (36%) | catalogued as rs755670829; called by muse, mutect2, varscan2
- MBNL1 | c.-790+462A>G | Intron (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- MGP | c.*62C>T | 3'UTR (SNP) | VAF 120/274 reads (44%) | called by mutect2, varscan2
- SEPTIN9 | c.722-36519C>A | Intron (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- ZNF971P | n.922A>C | RNA (SNP) | VAF 101/379 reads (27%) | called by muse, mutect2, varscan2
